Gene-level copy-number profile of tumor specimen TCGA-XF-A9SV-01A from TCGA case TCGA-XF-A9SV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 82.9 years (30,265 days).
Specimen TCGA-XF-A9SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.918b1f22-1acf-4ccd-833f-646ae91569b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cbca563-f45a-4a8c-9377-4d23452b0cf8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 253; copy number 2: 3,510; copy number 3: 16,533; copy number 4: 26,597; copy number 5: 3,866; copy number 6: 7,541; copy number 7: 1,228; copy number 8: 30; copy number 9: 22; copy number 14: 166; copy number 30: 5; copy number 31: 15; copy number 32: 20; copy number 43: 6; copy number 46: 6; copy number 52: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SV-01A-21D-A42D-01): tumor purity 0.63, ploidy 3.93, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 256 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,163,268–10,452,153, 11 genes, copy number 9 (within-gene range 4–9): RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS.
- chr2:8,721,081–9,109,865, 6 genes, copy number 43: KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4.
- chr2:9,473,658–10,211,725, 26 genes, copy number 32–46: IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261.
- chr2:10,439,968–10,689,987, 5 genes, copy number 30 (within-gene range 2–30): ODC1, SNORA80B, ODC1-DT, NOL10, AC007314.1.
- chr6:40,271,566–45,664,349, 166 genes, copy number 14 (within-gene range 4–14) (broad region; genes not listed).
- chr6:135,181,308–135,813,990, 13 genes, copy number 31: MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1.
- chr6:135,854,053–135,888,133, 2 genes, copy number 31: AL360178.1, AL360178.2.
- chr11:69,048,932–69,654,474, 16 genes, copy number 52: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1.
- chr12:66,767–277,123, 11 genes, copy number 9: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4.

Autosomal genes at a single copy (total copy number 1): 253. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
